Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64U, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64U-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A. Brain, right frontal mass, resection: Low-grade oligoastrocytoma (WHO grade II).

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies directed against antigens for IDH1 (R132H), p53, and Ki-67 (MIB-1). IDH1 (R132H) stain is positive in tumor cells, consistent with IDH1 mutation. p53 protein is positive in rare nuclei. Ki-67 (MIB-1) labeling index is low. The findings support the above diagnosis.

Interpreted by:

Report electronically signed by

Transcribed by:

ADDENDA:

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the

For interpretation, see

Transcribed by

Signed by

ALL EMBEDDED

continued next page Page 1 of 2

ICD-O-3
Oligoastrocytoma 9382/3
path
Site @ Brain, frontal lobe
C6CF 071.1
Brain, supratentorial NOS
071.0
JW 5/10/13

[page 2 of 2]
Preliminary Frozen Section Consultation:

A. Brain, right frontal mass, smears: Diffuse glioma. Hold over for final typing and grading.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "right frontal mass brain" is a 5.2 x 3.4 x 1.8 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

Block Summary:

Part A: Right frontal brain mass

- 1 Right frontal brain mass1
- 2 Right frontal brain mass2
- 3 Right frontal brain mass3
- 4 Right frontal brain mass4
- 5 Right frontal brain mass5
- 6 Right frontal brain mass6
- 7 Right frontal brain mass7
- 8 Right frontal brain mass8
- 9 Right frontal brain mass9
- 10 Right frontal brain mass10
- 11 Right frontal brain mass11
- 12 Right frontal brain mass12

ALL EMBEDDED

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 0cdd3504-5abe-4397-b6a6-b8657997b3d9 (TCGA-DB-A64U.7BE25474-4E80-403D-A999-EB2ADE02755C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).